Somatic mutation profile of tumor specimen C3N-00312-03 (aliquot CPT0009060006) from CPTAC case C3N-00312, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 68.8 years (25,123 days).
Specimen C3N-00312-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc47a78f-4c49-4558-bb84-cf6f7ddd463a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00312-31 (Blood Derived Normal), aliquot CPT0009090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b22f1d18-9af9-4147-8ec2-5b63b504ebf8

The open-access MAF lists 91 somatic variants for this specimen: 65 protein-altering or splice-affecting, 16 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 16, Frame Shift Del 7, Splice Site 5, 3'UTR 4, Splice Region 3, In Frame Del 2, Intron 2, 5'UTR 2, Nonsense Mutation 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CATSPERG | c.815C>G p.S272C | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.723); catalogued as rs1366216301; called by muse, mutect2, varscan2
- CHD7 | c.6499G>A p.V2167I | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as rs971937875; called by muse, mutect2, varscan2
- GGA3 | c.1445C>T p.S482F (on ENST00000537686 / NM_138619.4; = p.S449F on NM_014001.5) | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1178473582; called by muse, mutect2, varscan2
- HPS6 | c.629C>G p.P210R | Missense Mutation (SNP) | VAF 99/398 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs753587696; called by muse, mutect2, varscan2
- IFT81 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767705291; called by muse, mutect2, varscan2
- LPAR6 | c.756T>G p.Y252* | Nonsense Mutation (SNP) | VAF 30/125 reads (24%) | catalogued as rs944321155, CM153496; called by muse, mutect2, varscan2
- MAPT | c.1677C>G p.N559K (on ENST00000262410 / NM_001377265.1; = p.N167K on NM_005910.5) | Missense Mutation (SNP) | VAF 81/332 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52242881; called by muse, mutect2, varscan2
- PCLO | c.2974A>G p.K992E | Missense Mutation (SNP) | VAF 71/257 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.453); catalogued as rs1246670068; called by muse, mutect2, varscan2
- PHTF1 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as rs759006715; called by muse, mutect2, varscan2
- PPP1R12C | c.2008C>G p.P670A | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV52383486; called by muse, mutect2, varscan2
- RYR1 | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 87/386 reads (23%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.987); catalogued as COSV62108397; called by muse, mutect2, varscan2
- SH3PXD2A | c.1555C>T p.R519W (on ENST00000369774 / NM_001365079.1; = p.R491W on NM_014631.2) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100280177, COSV60118315; called by muse, mutect2, varscan2
- TCOF1 | c.2659-1G>C p.X887_splice (on ENST00000377797 / NM_001135243.1; = p.X810_splice on NM_000356.4) | Splice Site (SNP) | VAF 105/389 reads (27%) | catalogued as COSV60345624; called by muse, mutect2, varscan2
- YLPM1 | c.4604C>A p.S1535* | Nonsense Mutation (SNP) | VAF 72/154 reads (47%) | catalogued as COSV53119977; called by muse, mutect2, varscan2
- ZNF655 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs774474239, COSV53159970; called by muse, mutect2, varscan2
- ZNF790 | c.694G>T p.G232W | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63213016; called by muse, mutect2, varscan2
- ADCY9 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 67/290 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ASIC2 | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- BCAN | c.2089G>T p.G697C | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CENPV | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CETN2 | c.162+2C>T p.X54_splice | Splice Site (SNP) | VAF 21/32 reads (66%) | called by mutect2, varscan2
- CFAP74 | c.4664_4666del p.P1555del | In Frame Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- COL6A6 | c.4783G>C p.E1595Q | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- CRYBG1 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAI4 | c.1291+2T>A p.X431_splice | Splice Site (SNP) | VAF 63/184 reads (34%) | called by muse, mutect2, varscan2
- DNAJC1 | c.635+2T>C p.X212_splice | Splice Site (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- DNM2 | c.2443C>A p.P815T (on ENST00000355667 / NM_001005360.3; = p.P811T on NM_004945.3) | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EYA3 | c.1625A>T p.E542V | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAL | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- GCN1 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRN | c.934-2A>G p.X312_splice | Splice Site (SNP) | VAF 60/275 reads (22%) | called by muse, mutect2, varscan2
- HCN4 | c.2281G>A p.A761T | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HMCN1 | c.9224C>A p.T3075N | Missense Mutation (SNP) | VAF 107/410 reads (26%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- HSPA8 | c.1677A>T p.Q559H | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- IGKV1-12 | c.257del p.G86Afs*? | Frame Shift Del (DEL) | VAF 38/214 reads (18%) | called by mutect2, varscan2
- ITPRID2 | c.332del p.S111Ifs*44 | Frame Shift Del (DEL) | VAF 26/158 reads (16%) | called by mutect2, pindel, varscan2
- KCNC2 | c.1660C>A p.P554T | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- LHX6 | c.253-4C>A | Splice Region (SNP) | VAF 40/138 reads (29%) | called by muse, mutect2, varscan2
- LILRB2 | c.1615A>G p.T539A | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- LRP2 | c.2873T>G p.L958R | Missense Mutation (SNP) | VAF 98/365 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- MTRF1L | c.188A>C p.E63A | Missense Mutation (SNP) | VAF 98/429 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MYO7A | c.2272T>G p.F758V | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NBPF14 | c.7948C>G p.L2650V | Missense Mutation (SNP) | VAF 71/289 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- NLGN2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 123/423 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NR2C1 | c.89A>T p.Q30L | Missense Mutation (SNP) | VAF 80/252 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OBSCN | c.9382T>C p.W3128R | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2L3 | c.826T>G p.F276V | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- OR4Q2 | c.166A>G p.N56D | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- PBRM1 | c.3755del p.N1252Mfs*17 (on ENST00000296302 / NM_001366071.2; = p.N1227Mfs*17 on NM_018313.5) | Frame Shift Del (DEL) | VAF 95/275 reads (35%) | called by mutect2, pindel, varscan2
- PPP2CA | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC16A12 | c.853G>C p.V285L | Missense Mutation (SNP) | VAF 80/315 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- SORBS2 | c.286G>A p.D96N (on ENST00000284776 / NM_021069.5; = p.D142N on NM_003603.6) | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAT6 | c.1097A>G p.K366R | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- SYNE2 | c.13226_13270del p.M4409_S4424delinsT | In Frame Del (DEL) | VAF 24/146 reads (16%) | called by mutect2, pindel
- TMEM108 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- TRGV8 | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTLL7 | c.1861_1862delinsA p.F621Ifs*6 | Frame Shift Del (DEL) | VAF 50/359 reads (14%) | called by pindel, varscan2*
- UBE2D3 | c.27A>G p.E9= | Splice Region (SNP) | VAF 39/181 reads (22%) | called by muse, mutect2, varscan2
- UNC13B | c.1215G>A p.G405= | Splice Region (SNP) | VAF 41/123 reads (33%) | called by muse, mutect2, varscan2
- USH2A | c.15174del p.L5059Cfs*3 | Frame Shift Del (DEL) | VAF 84/288 reads (29%) | called by mutect2, pindel, varscan2
- VHL | c.402dup p.L135Ifs*9 | Frame Shift Ins (INS) | VAF 80/273 reads (29%) | called by mutect2, pindel, varscan2
- WDR54 | c.1003_1004del p.*335Rfs*? | Frame Shift Del (DEL) | VAF 29/131 reads (22%) | called by pindel, varscan2
- ZNF19 | c.86C>A p.T29N | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ZNF649 | c.1119del p.F374Lfs*88 | Frame Shift Del (DEL) | VAF 46/147 reads (31%) | called by mutect2, pindel, varscan2
- ZNF79 | c.600A>C p.K200N | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- ADH4 | c.537A>C p.G179= | Silent (SNP) | VAF 52/174 reads (30%) | called by muse, mutect2, varscan2
- ANXA2R | c.285G>T p.G95= | Silent (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- AUTS2 | c.102G>T p.A34= | Silent (SNP) | VAF 10/39 reads (26%) | called by muse, varscan2
- BRD3 | c.1161C>T p.C387= | Silent (SNP) | VAF 54/186 reads (29%) | catalogued as rs1185563179, COSV100325348; called by muse, mutect2, varscan2
- CALB2 | c.516C>T p.G172= | Silent (SNP) | VAF 62/212 reads (29%) | called by muse, mutect2, varscan2
- CDK13 | c.1035A>T p.G345= | Silent (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- CSMD2 | c.6570C>T p.N2190= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs377152497; called by muse, mutect2
- DDX17 | c.1581A>G p.L527= | Silent (SNP) | VAF 113/394 reads (29%) | catalogued as rs369638680; called by muse, mutect2, varscan2
- DST | c.10587A>G p.V3529= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs1292771928; called by muse, mutect2, varscan2
- EXOSC9 | c.468C>G p.A156= | Silent (SNP) | VAF 28/124 reads (23%) | called by muse, mutect2, varscan2
- FBLN7 | c.930C>T p.Y310= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as rs148395500; called by muse, mutect2, varscan2
- ITGA7 | c.3165G>A p.L1055= (on ENST00000555728; = p.L1011= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 136/491 reads (28%) | catalogued as COSV57696802; called by muse, mutect2, varscan2
- PDE8B | c.792A>G p.K264= | Silent (SNP) | VAF 38/196 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.24864T>C p.A8288= (on ENST00000591111; = p.A7361= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/173 reads (25%) | called by muse, mutect2, varscan2
- TUBB6 | c.270C>T p.F90= | Silent (SNP) | VAF 68/284 reads (24%) | catalogued as rs1324251587, COSV100480964; called by muse, varscan2
- ZFP36 | c.348G>T p.R116= (on ENST00000594442; = p.R110= on NM_003407.5) | Silent (SNP) | VAF 46/185 reads (25%) | called by muse, mutect2, varscan2
- BRCA1 | c.*790G>T | 3'UTR (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- BTBD10 | c.101+5043A>C | Intron (SNP) | VAF 32/113 reads (28%) | catalogued as rs1194565378; called by muse, mutect2, varscan2
- CDK9 | c.-82C>A | 5'UTR (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2
- COG6 | c.-61G>A | 5'UTR (SNP) | VAF 81/359 reads (23%) | catalogued as rs770910922; called by muse, mutect2, varscan2
- DNPH1 | c.196+192T>C | Intron (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2, varscan2
- MFSD4B | c.*415T>A | 3'UTR (SNP) | VAF 40/163 reads (25%) | called by muse, mutect2, varscan2
- PAK1 | c.*115T>A | 3'UTR (SNP) | VAF 42/168 reads (25%) | called by muse, mutect2, varscan2
- POM121L9P | n.773C>T | RNA (SNP) | VAF 52/390 reads (13%) | catalogued as rs1209058384; called by muse, mutect2
- SEC31B | c.*11del | 3'UTR (DEL) | VAF 41/151 reads (27%) | called by mutect2, pindel, varscan2
- XIAP | chrX:123860160 C>T | 5'Flank (SNP) | VAF 136/246 reads (55%) | called by muse, mutect2, varscan2
